TARGET case TARGET-30-PAJXLE — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/7d1edfd4-b5c8-5a36-8952-78b9b1b48a5d

Demographics
Sex at birth: male.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 2.0 years (720 days); Year of diagnosis: 1986.

Biospecimens (2 samples)
- Sample TARGET-30-PAJXLE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAJXLE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
